Gene-level copy-number profile of tumor specimen C3L-06195-03 from CPTAC case C3L-06195, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 52.0 years (19,009 days).
Specimen C3L-06195-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7596df1c-41cd-4604-9431-a2b50f695257.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06195-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/8da719d2-ea04-4d08-bf05-6b43ba509b4b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 198; copy number 2: 13,130; copy number 3: 31,052; copy number 4: 9,302; copy number 5: 1,368; copy number 6: 994; copy number 7: 2,330; copy number 8: 14.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:45,197,674–45,197,770, 1 gene (within-gene range 0–4): MIR586.
- chr6:170,695,313–170,696,950, 1 gene: AL731661.1.
- chr12:9,852,984–9,870,136, 2 genes: CLEC2B, AC091814.1.
- chr17:22,233,926–22,266,392, 1 gene: LINC02002.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,344 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:62,275,361–62,275,678, 1 gene, copy number 7: AC128676.1.
- chr8:46,028,804–132,760,712, 1,227 genes, copy number 7 (broad region; genes not listed).
- chr8:132,866,958–145,066,685, 264 genes, copy number 7 (broad region; genes not listed).
- chr14:18,333,726–18,412,264, 3 genes, copy number 8: CR383658.1, RNU6-458P, CR383658.2.
- chr17:57,834,781–83,240,804, 841 genes, copy number 7–8 (broad region; genes not listed).
- chr21:10,612,455–13,120,807, 8 genes, copy number 7: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 197. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
